Surgical pathology report (de-identified scan), TCGA case TCGA-06-6388, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-6388-01A (Primary Tumor).

[page 1 of 5]
Surgical Pathology Report

CLINICAL HISTORY

[REDACTED] recently had surgery and antibiotics for an [REDACTED].
On MRI there is a large, centrally necrotic, heterogeneously enhancing mass in the right frontal lobe. The mass abuts with convexity dura and extends to the ventricle, with minimal to no vasogenic edema.

OPERATIVE DIAGNOSES

Operation/Specimen: A: Brain, excision biopsy
B: Brain, resection

PATHOLOGICAL DIAGNOSIS:

A and B. Brain, site not specified, excisional biopsy and resection:

1. Glioblastoma.
2. MIB-1 proliferation index: 33%.
- See Microscopy Description and Comment.

COMMENT

The sections contain portions of cerebrum that are sparsely to heavily infiltrated to effaced by an astrocytic neoplastic proliferation that has nuclear anaplasia, appreciable mitotic activity and a high proliferation index of about 33%, exuberant microvascular cellular proliferation, and zones of necrosis, many of them palisaded. There are microscopic areas of neoplasm within the leptomeningeal space.

The neoplasm has features characteristic of a glioblastoma (WHO IV).

[REDACTED]

[page 2 of 5]
=====

PROCEDURES/ADDENDA

PCR for EGFR variant III mutation

Date Ordered: [REDACTED] Date Reported: [REDACTED]

Interpretation

NEGATIVE - No evidence of EGFRvIII mutation is detected

Results-Comments

TEST DESCRIPTION: Testing performed on RNA extracted manually
microdissected
paraffin block

The epidermal growth factor receptor (EGFR) is an attractive molecular target in glioblastoma because it is amplified, overexpressed, and/or mutated in up to 40% to 50% of patients. Epidermal growth factor receptor variant III

(EGFRvIII) is an oncogenic, constitutively active mutant form of EGFR that is

commonly expressed in glioblastoma. Cell culture and in vivo models of glioblastoma have demonstrated EGFRvIII as defining prognostically distinct

subgroups of glioblastomas. Additionally, the presence of EGFRvIII has been

shown to sensitize tumors to EGFR tyrosine kinase inhibitors when the tumor

suppressor protein PTEN is intact. RNA is extracted from formalin fixed,

paraffin embedded tissue samples and reverse transcribed to cDNA. The cDNA is

then amplified using standard PCR technique for DNA templates. PCR products

are detected by gel electrophoresis. The limit of detection of this assay has

been determined to be approximately 5 mutant cells in 100 normal cells.

FDA Comment: The above data are not to be construed as the results from a

stand alone diagnostic test. This test was developed and its performance

characteristics determined by the [REDACTED] laboratory as required by CLIA [REDACTED] regulations. It has not been cleared or approved for

specific uses by the U.S. Food and Drug Administration (FDA). The FDA has

determined that such clearance or approval is not necessary. These results are

provided for informational purposes only, and should be interpreted only in

the context of established procedures and/or diagnostic criteria.

[REDACTED]

[page 3 of 5]
NEGATIVE: No evidence of methylated MGMT promoter is detected.

Results-Comments

Testing performed on DNA extracted from manually micro dissected paraffin block

TEST DESCRIPTION: Patients with glioma containing a methylated MGMT promoter

have been shown to benefit from therapy with alkylating agents.

Assessment of

MGMT promoter methylation status involves bisulfite treatment of DNA followed

by real-time PCR amplification (MethyLight) of methylated and unmethylated DNA

sequences. The analytic sensitivity of this assay was determined by serial

dilution of methylated positive control DNA into unmethylated DNA, and was

assessed to be 1% of methylated DNA in the background of unmethylated DNA.

Factors such as the presence of >50% non-neoplastic cells in the sample, or

extensive tissue necrosis, may preclude the detection of methylated MGMT

promoter sequences.

FDA COMMENT: The above data are not to be construed as the results from a

stand alone diagnostic test. This test was developed and its performance

characteristics determined by the [REDACTED] laboratory as required by CLIA [REDACTED] regulations. It has not been cleared or approved for

specific uses by the U.S. Food and Drug Administration (FDA). The FDA has

determined that such clearance or approval is not necessary. These results are

provided for informational purposes only, and should be interpreted only in

the context of established procedures and/or diagnostic criteria.

INTRA-OPERATIVE CONSULTATION

A.

Brain, excision biopsy: Glioma, high histologic grade (consistent with glioblastoma, other). 1 block + touch prep + crush prep cytology.

Telepathology consultation with Dr. [REDACTED]

Frozen section performed at [REDACTED]

[REDACTED] and called to the Physician of record.

[page 4 of 5]
GROSS DESCRIPTION

A.

Brain, excision biopsy:

Submitted is a 1.0 x 1.0 x 0.5 cm portion of soft gray-white tissue.

Cassettes: A1 Frozen section remnant. 2 and 3- remaining

B.

Brain, resection

CONTAINER LABEL: brain tumor

FIXATIVE: Formalin. NO. PIECES: Multiple ragged soft gray white tissue

fragments. SIZE/VOL: aggregating to 9.5 x 5.5 x 2.0 cm. CASSETTES: 26, NS.

MICROSCOPIC DESCRIPTION

IMMUNOHISTOCHEMISTRY: The GFAP demonstrates prominent gliofibrillogenesis by the neoplastic cells in solid areas. About 30% of the neoplastic cells strongly over express the p53 protein. With the MIB-1 the proliferation index is about 33% in the more active areas.

ICD-9(s):

191.9 191.9

Histo Data

Part A: Brain, excision biopsy

Taken:	Received:		
Stain/cnt	Block	Ordered	Comment
FS H/E x 1	1		
H/E x 1	1		
TPS H/E x 1	1		
EGFR vIII-slides x 1	2		
mGFAP-DA x 1	2		
H/E x 1	2		
MGMT-curls x 1	2		
MIB1-DA x 1	2		
P53DO7 x 1	2		
H/E x 1	3		

Part B: Brain, resection

Taken:	Received:		
Stain/cnt	Block	Ordered	Comment
H/E x 1	1		
H/E x 1	2		

[page 5 of 5]
H/E x 1 3
H/E x 1 4
H/E x 1 5
H/E x 1 6
H/E x 1 7
MIB1-DA x 1 7
H/E x 1 8
H/E x 1 9
H/E x 1 10
H/E x 1 11
H/E x 1 12
H/E x 1 13
H/E x 1 14
H/E x 1 15
H/E x 1 16
H/E x 1 17
H/E x 1 18
H/E x 1 19
H/E x 1 20
H/E x 1 21
H/E x 1 22
H/E x 1 23
H/E x 1 24
H/E x 1 25
H/E x 1 26
*** End of Report ***

Source: NCI Genomic Data Commons file f2c54349-9c09-4abe-b8f1-cce0f05f8b55 (TCGA-06-6388.FC0566BF-E3A2-417D-8BCE-BA5238521CD5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).